Somatic mutation profile of tumor specimen ALCH-B2V6-TTP1-A (aliquot ALCH-B2V6-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2V6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 80.2 years (29,295 days).
Specimen ALCH-B2V6-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e7b056b-23ac-4d12-b015-449a17f9ceb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2V6-NB1-A (Blood Derived Normal), aliquot ALCH-B2V6-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66d0eacd-9d77-49e2-a8a3-e5b4c8a49fe1

The open-access MAF lists 442 somatic variants for this specimen: 310 protein-altering or splice-affecting, 79 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 263, Silent 79, Intron 29, Nonsense Mutation 25, 3'UTR 10, Frame Shift Del 7, RNA 5, Splice Site 5, 5'Flank 4, Frame Shift Ins 3, 5'UTR 3, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 61/109 reads (56%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACKR1 | c.271C>A p.Q91K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as rs750778047; called by muse, mutect2, varscan2
- ALS2 | c.1402G>A p.V468M | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1412043555; ClinVar: uncertain significance; called by muse, mutect2
- ANHX | c.375G>T p.K125N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV101376517; called by muse, mutect2, varscan2
- ATF6B | c.492G>C p.K164N | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.172); catalogued as COSV64351522; called by muse, mutect2, varscan2
- ATP6V0D2 | c.102C>G p.I34M | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as COSV53416885; called by muse, mutect2, varscan2
- ATRNL1 | c.3367G>A p.E1123K | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as COSV58093415; called by muse, mutect2, varscan2
- BDP1 | c.1123C>G p.L375V | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62432483; called by muse, mutect2
- C14orf39 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 12/154 reads (8%) | catalogued as COSV100407843; called by muse, mutect2
- CASR | c.2902G>T p.E968* (on ENST00000490131; = p.E1045* on NM_000388.4) | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV56139805; called by muse, mutect2, varscan2
- CCDC191 | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs1278820953, COSV55669830, COSV55673124; called by muse, mutect2
- CD40 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64847742; called by muse, mutect2, varscan2
- CDX4 | c.137C>A p.A46E | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as rs1246151225, COSV65171630, COSV65171752; called by muse, mutect2, varscan2
- CLEC14A | c.521A>G p.Q174R | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs1401023737, COSV100643621; called by muse, mutect2, varscan2
- CNTNAP2 | c.2785G>T p.G929C | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV100665060, COSV100673046; called by muse, mutect2, varscan2
- COG4 | c.546G>A p.G182= | Splice Region (SNP) | VAF 41/154 reads (27%) | catalogued as rs1363696522, COSV60422919; called by muse, mutect2, varscan2
- COL11A1 | c.2648del p.G883Vfs*99 | Frame Shift Del (DEL) | VAF 40/313 reads (13%) | catalogued as COSV100615990; called by mutect2, pindel, varscan2
- COL11A2 | c.4018G>C p.D1340H (on ENST00000341947 / NM_080680.3; = p.D1233H on NM_080679.2) | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV100553704; called by muse, mutect2
- COL4A6 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs913845999; called by muse, mutect2, varscan2
- COL6A3 | c.7834G>T p.A2612S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); catalogued as rs1172047660, COSV55081279; called by muse, mutect2
- CPS1 | c.1747C>A p.P583T | Missense Mutation (SNP) | VAF 79/314 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51814144; called by muse, mutect2, varscan2
- CRYBG2 | c.1427C>T p.T476I | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.062); catalogued as rs1453962389; called by muse, mutect2
- CTNNA2 | c.2407G>T p.G803* | Nonsense Mutation (SNP) | VAF 15/61 reads (25%) | catalogued as COSV58144783; called by muse, mutect2, varscan2
- DCAF4L2 | c.847C>G p.Q283E | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.155); catalogued as rs189636421; called by muse, mutect2, varscan2
- DES | c.369C>G p.I123M | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs2666105; called by mutect2, varscan2
- DIO1 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV59518010; called by muse, mutect2, varscan2
- DLK1 | c.526C>A p.P176T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.811); catalogued as COSV57993696; called by muse, mutect2, varscan2
- DNAH1 | c.3655C>T p.R1219C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs376325553; called by muse, mutect2, varscan2
- DNAH6 | c.7948G>A p.E2650K | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.091); catalogued as rs1212357482; called by muse, mutect2
- EDA | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.028); catalogued as COSV101000130, COSV65784191; called by muse, mutect2, varscan2
- ENTHD1 | c.1313C>A p.S438* | Nonsense Mutation (SNP) | VAF 13/164 reads (8%) | catalogued as COSV57319664; called by muse, mutect2
- F9 | c.1068G>T p.W356C | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM940637, CM940638, CM940639; called by muse, mutect2, varscan2
- FAM171A1 | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.534); catalogued as rs752713972; called by muse, mutect2, varscan2
- FAM205A | c.2257G>C p.G753R | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.06); catalogued as rs776226351; called by muse, mutect2, varscan2
- FAM47B | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs1184635361, COSV61452543; called by muse, mutect2
- FAT3 | c.778A>C p.N260H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53158680; called by muse, mutect2, varscan2
- FBXL7 | c.425G>T p.R142L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100309458; called by muse, mutect2, varscan2
- GABRG3 | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV100406812; called by muse, mutect2, varscan2
- GBA3 | c.439C>A p.Q147K | Missense Mutation (SNP) | VAF 16/355 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV72438267; called by muse, mutect2
- GPR158 | c.2724C>A p.S908R | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV66283644; called by muse, mutect2, varscan2
- GPR173 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1556805906; called by muse, mutect2, varscan2
- GRIN2A | c.1184C>A p.S395Y | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV58059975; called by muse, mutect2, varscan2
- HRNR | c.5740G>A p.G1914R | Missense Mutation (SNP) | VAF 130/1523 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.093); catalogued as rs751236412, COSV64260517; called by muse, mutect2
- HSPA2 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 15/396 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); catalogued as rs1423961088; called by muse, mutect2
- IGSF9 | c.2089G>A p.V697M (on ENST00000368094 / NM_001135050.2; = p.V681M on NM_020789.4) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.73); catalogued as rs1245702945; called by muse, mutect2, varscan2
- IL18BP | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.011); catalogued as rs1423995334; called by muse, mutect2
- ITGA7 | c.2165C>T p.A722V (on ENST00000555728; = p.A678V on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.026); catalogued as rs1232299627; called by muse, varscan2
- JAKMIP1 | c.1085G>T p.R362L | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51525099; called by muse, mutect2, varscan2
- KCNT2 | c.3340G>T p.E1114* | Nonsense Mutation (SNP) | VAF 69/388 reads (18%) | catalogued as COSV99652837; called by muse, mutect2, varscan2
- KIAA1109 | c.6703G>C p.E2235Q | Missense Mutation (SNP) | VAF 17/217 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as COSV52671922; called by muse, mutect2
- KIAA1614 | c.3511G>A p.G1171S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs145566296; called by mutect2, varscan2
- LIPI | c.1301C>A p.S434Y | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as COSV60710154; called by muse, mutect2, varscan2
- LLGL2 | c.356T>C p.L119P | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.199); catalogued as rs1018893764; called by muse, varscan2
- LRRTM3 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747974816; called by muse, mutect2, varscan2
- MAGEB6 | c.1096G>T p.E366* | Nonsense Mutation (SNP) | VAF 12/205 reads (6%) | catalogued as COSV66872599; called by muse, mutect2
- MED12L | c.3361G>C p.A1121P | Missense Mutation (SNP) | VAF 66/91 reads (73%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); catalogued as COSV56402659; called by muse, mutect2, varscan2
- METTL3 | c.988C>T p.H330Y | Missense Mutation (SNP) | VAF 8/137 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99398526; called by muse, mutect2
- MINAR1 | c.977C>A p.A326E | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as rs766073576; called by muse, mutect2, varscan2
- MTCH1 | c.691G>T p.A231S | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.412); catalogued as rs1184627045; called by muse, mutect2, varscan2
- MUC12 | c.13676C>A p.P4559Q (on ENST00000379442; = p.P4416Q on NM_001164462.1) | Missense Mutation (SNP) | VAF 53/553 reads (10%) | SIFT deleterious (0); catalogued as rs773238256, COSV101060104; called by muse, mutect2, varscan2
- MUC5B | c.5747C>T p.T1916M | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs772902423, COSV71590678; called by muse, mutect2, varscan2
- MYH6 | c.2039G>T p.R680L | Missense Mutation (SNP) | VAF 80/159 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as COSV62452989, COSV62455174; called by muse, mutect2, varscan2
- NABP1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 62/246 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs142344259, COSV100322989; called by muse, mutect2, varscan2
- NDST4 | c.2494C>A p.P832T | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV52130088; called by muse, mutect2, varscan2
- NMI | c.364A>G p.S122G | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755341104; called by muse, mutect2, varscan2
- NOXO1 | c.111C>A p.F37L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV50191300; called by muse, mutect2, varscan2
- NPR2 | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV61310225; called by muse, mutect2, varscan2
- OR2B11 | c.458G>A p.W153* | Nonsense Mutation (SNP) | VAF 9/15 reads (60%) | catalogued as rs1378020374; called by muse, mutect2, varscan2
- OR4C16 | c.4C>G p.Q2E | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV58944451; called by muse, mutect2, varscan2
- OR51B4 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100971158, COSV66517532; called by muse, mutect2, varscan2
- OR51F1 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV58579137; called by muse, mutect2, varscan2
- OR5AR1 | c.247G>T p.A83S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs772609353, COSV57255397; called by muse, mutect2, varscan2
- OR6C75 | c.126C>G p.I42M | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV58552107; called by muse, mutect2
- PAX4 | c.623C>G p.S208C | Missense Mutation (SNP) | VAF 6/156 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.106); catalogued as rs1240004151; called by muse, mutect2
- PLCE1 | c.1812G>A p.V604= | Splice Region (SNP) | VAF 20/201 reads (10%) | catalogued as rs1487763804; called by muse, mutect2, varscan2
- PLEKHA8 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs201994634, COSV99322522; called by muse, mutect2, varscan2
- PLP1 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.999); catalogued as COSV58277193; called by muse, mutect2, varscan2
- PPP4R3C | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 27/165 reads (16%) | catalogued as COSV69081134; called by muse, mutect2, varscan2
- PTPRC | c.3032C>G p.S1011* | Nonsense Mutation (SNP) | VAF 18/356 reads (5%) | catalogued as COSV61414323; called by muse, mutect2
- RADIL | c.855C>A p.S285R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV101271280; called by muse, mutect2, varscan2
- RAP1B | c.371G>C p.R124T | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99164958; called by muse, mutect2
- RBL1 | c.3170G>A p.R1057Q | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs956951052; called by muse, mutect2
- RBL1 | c.2712G>C p.M904I | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV60328203, COSV60330499; called by muse, mutect2
- RBM38 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV61134840; called by muse, mutect2, varscan2
- RITA1 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.333); catalogued as rs199689319; called by muse, mutect2, varscan2
- RNASE12 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV60088079; called by muse, mutect2, varscan2
- RUBCN | c.1261+6G>A | Splice Region (SNP) | VAF 8/36 reads (22%) | catalogued as rs377291607; called by muse, mutect2, varscan2
- RUNX1T1 | c.1181G>T p.R394L (on ENST00000265814 / NM_001198628.1; = p.R367L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99750579; called by muse, varscan2
- RYR1 | c.2824G>A p.D942N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.345); catalogued as rs869312736, COSV100616635; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.4603C>A p.P1535T | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100769615, COSV63660633; called by muse, mutect2, varscan2
- RYR2 | c.4750C>A p.P1584T | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV63669076; called by mutect2, varscan2
- SCG2 | c.1619A>T p.E540V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV100544605; called by muse, mutect2, varscan2
- SCN1A | c.1733G>C p.R578T | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV57660982; called by muse, mutect2, varscan2
- SLITRK5 | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as rs781758220, COSV100280608; called by muse, mutect2, varscan2
- SMAD1 | c.1090C>G p.H364D | Missense Mutation (SNP) | VAF 8/189 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV100129747; called by muse, mutect2
- SOHLH1 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.19); PolyPhen benign (0.12); catalogued as rs370080218; called by muse, mutect2, varscan2
- STAG2 | c.3448C>G p.Q1150E | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.005); catalogued as COSV54352032; called by muse, mutect2
- SYT2 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66142021; called by muse, mutect2, varscan2
- TAF3 | c.685del p.S229Lfs*35 | Frame Shift Del (DEL) | VAF 26/132 reads (20%) | catalogued as COSV100720521; called by mutect2, pindel, varscan2
- TLCD1 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.096); catalogued as rs200266791, COSV52046928; called by muse, mutect2
- TMTC1 | c.1778C>A p.A593D (on ENST00000539277 / NM_001193451.2; = p.A485D on NM_175861.3) | Missense Mutation (SNP) | VAF 125/272 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV55479313; called by muse, mutect2, varscan2
- TTC30A | c.1926del p.K643Rfs*11 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | catalogued as COSV100826249; called by mutect2, pindel, varscan2
- TTN | c.40678C>T p.H13560Y (on ENST00000591111; = p.H6136Y on NM_003319.4) | Missense Mutation (SNP) | VAF 73/299 reads (24%) | PolyPhen benign (0.003); catalogued as COSV100623164; called by muse, mutect2, varscan2
- UBXN8 | c.569_570+1del | In Frame Del (DEL) | VAF 18/63 reads (29%) | catalogued as rs747763460; called by pindel, varscan2
- UNC13C | c.4269-2A>T p.X1423_splice | Splice Site (SNP) | VAF 18/196 reads (9%) | catalogued as rs1199337918; called by muse, mutect2
- USP33 | c.931A>G p.K311E | Missense Mutation (SNP) | VAF 55/333 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as rs533635679; called by muse, mutect2, varscan2
- USP54 | c.1718G>T p.R573L | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60442985; called by muse, mutect2, varscan2
- WDR49 | c.2059G>C p.E687Q (on ENST00000308378 / NM_001366158.1; = p.E1028Q on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/347 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.037); catalogued as COSV52986967; called by muse, mutect2
- ZNF611 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as COSV60539981; called by muse, mutect2, varscan2
- ZNF705G | c.677G>C p.R226T | Missense Mutation (SNP) | VAF 26/303 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as rs764392928; called by muse, mutect2
- ZNF721 | c.971G>A p.G324E (on ENST00000338977; = p.G336E on NM_133474.4) | Missense Mutation (SNP) | VAF 24/299 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs879986292, COSV59090057; called by muse, mutect2
- ZNF831 | c.1890G>T p.R630S | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV64040461; called by muse, mutect2
- ABCA13 | c.12144G>T p.Q4048H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ABCG4 | c.899C>G p.P300R | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- ADAMTS2 | c.1648T>G p.C550G | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTS2 | c.1117C>A p.P373T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRB3 | c.2178G>T p.K726N | Missense Mutation (SNP) | VAF 110/245 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- AEBP1 | c.2984C>A p.A995D | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- AHNAK | c.13283T>G p.I4428S | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- ALDH7A1 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALMS1 | c.10864G>C p.E3622Q | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AMER1 | c.2141A>T p.Q714L | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ANK2 | c.11630T>C p.I3877T | Missense Mutation (SNP) | VAF 57/320 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- ANKRD2 | c.946C>A p.P316T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- ANKRD45 | c.779G>T p.S260I | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); called by muse, mutect2
- AOX1 | c.725T>A p.M242K | Missense Mutation (SNP) | VAF 67/302 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- APBB1IP | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- ASXL3 | c.3208G>T p.A1070S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATF4 | c.35dup p.L12Ffs*17 | Frame Shift Ins (INS) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- BAZ1B | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- BCOR | c.5155G>T p.E1719* (on ENST00000378444 / NM_001123385.2; = p.E1685* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 77/163 reads (47%) | called by muse, mutect2, varscan2
- BCR | c.590C>G p.S197W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- BRDT | c.1673C>A p.T558K | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- BRINP2 | c.2288T>A p.L763Q | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- BSN | c.5478C>A p.S1826R | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by muse, varscan2
- C11orf24 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- C5 | c.1832G>C p.G611A | Missense Mutation (SNP) | VAF 8/220 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.253); called by muse, mutect2
- C7orf31 | c.916G>T p.E306* | Nonsense Mutation (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- CACNA1A | c.2055G>T p.Q685H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- CADPS | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CALML6 | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- CASP8AP2 | c.3740C>G p.S1247C | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); called by muse, mutect2
- CCDC47 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.188); called by muse, mutect2
- CCDC63 | c.230T>A p.L77* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- CD247 | c.376A>C p.I126L (on ENST00000362089 / NM_198053.3; = p.I125L on NM_000734.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.715); called by muse, mutect2
- CDC5L | c.1229C>G p.S410C | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); called by muse, mutect2
- CDH9 | c.414G>T p.Q138H | Missense Mutation (SNP) | VAF 63/373 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- CDIN1 | c.179A>T p.H60L | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.042); called by muse, mutect2
- CDKL5 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); called by muse, mutect2
- CELF2 | c.157G>C p.E53Q (on ENST00000416382 / NM_001025077.3; = p.E60Q on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, mutect2
- CHRNA4 | c.403G>T p.V135F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CIP2A | c.2442G>C p.K814N | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, mutect2
- CLCN1 | c.2776T>A p.S926T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CNTNAP4 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- COL4A5 | c.3573C>A p.N1191K | Missense Mutation (SNP) | VAF 32/312 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPA1 | c.653A>T p.E218V | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2
- CTPS2 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTSA | c.436G>C p.D146H | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CUBN | c.1112-2A>T p.X371_splice | Splice Site (SNP) | VAF 34/134 reads (25%) | called by muse, mutect2, varscan2
- CUL3 | c.265G>T p.V89L | Missense Mutation (SNP) | VAF 67/239 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- CUL5 | c.617A>G p.Y206C | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CUL5 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- CYP11B1 | c.576C>G p.I192M | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.11); called by muse, mutect2
- CYP4A11 | c.838C>A p.L280M | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- DCC | c.957T>G p.I319M | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- DMAP1 | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); called by muse, mutect2
- DNASE2B | c.522C>G p.F174L | Missense Mutation (SNP) | VAF 32/392 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.028); called by muse, mutect2
- DOCK11 | c.1090A>T p.N364Y | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2
- DOP1B | c.5783G>T p.R1928L | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DRD1 | c.1217C>A p.A406E | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- E2F7 | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 11/310 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EGFLAM | c.2598G>T p.M866I (on ENST00000354891 / NM_001205301.2; = p.M858I on NM_152403.4) | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.132); called by muse, mutect2
- ENC1 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.962); called by muse, mutect2
- EPHB1 | c.2377C>T p.P793S | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- ETNPPL | c.868G>T p.V290L | Missense Mutation (SNP) | VAF 87/169 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- EZHIP | c.1355C>A p.S452Y | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- FAM120C | c.1015C>G p.L339V | Missense Mutation (SNP) | VAF 10/257 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM184A | c.3253C>T p.P1085S | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- FANCM | c.1961G>T p.R654L | Missense Mutation (SNP) | VAF 120/211 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FAT2 | c.197A>T p.Q66L | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBN1 | c.7859C>A p.A2620D | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- FBN2 | c.4641T>A p.C1547* | Nonsense Mutation (SNP) | VAF 76/258 reads (29%) | called by muse, mutect2, varscan2
- FBN2 | c.616C>A p.Q206K | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.173); called by muse, mutect2
- FCGBP | c.8469C>A p.H2823Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.108); called by muse, varscan2
- FRMPD1 | c.572A>T p.Q191L | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- GJD2 | c.565C>G p.L189V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNAI1 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- GNE | c.1910-13_1913del p.X637_splice (on ENST00000396594 / NM_001128227.3; = p.X606_splice on NM_005476.7 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 18/124 reads (15%) | called by mutect2, pindel
- GRHL2 | c.786G>T p.Q262H | Missense Mutation (SNP) | VAF 65/208 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- GTDC1 | c.1133T>C p.L378S (on ENST00000344850 / NM_001354361.1; = p.L293S on NM_024659.6 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- HIP1 | c.2690G>C p.R897T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HIVEP2 | c.2321C>G p.S774* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- HS3ST1 | c.506del p.K169Sfs*67 | Frame Shift Del (DEL) | VAF 39/108 reads (36%) | called by mutect2, pindel, varscan2
- HSCB | c.444G>C p.E148D | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.235T>A p.Y79N | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- IGKV1-9 | c.48G>T p.W16C | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- INTS6 | c.877C>G p.Q293E | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.776); called by muse, mutect2
- INTS6L | c.564C>A p.S188R | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- ITSN1 | c.4880C>T p.S1627F | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- JAKMIP1 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- JMJD1C | c.1594C>G p.Q532E | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.366); called by muse, varscan2
- KCNA10 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.283); called by muse, mutect2
- KIAA1328 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2
- KIAA1614 | c.3510del p.G1171Afs*32 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | called by mutect2, varscan2
- LEXM | c.520A>C p.N174H | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP1 | c.363G>C p.Q121H | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- LTN1 | c.3253G>A p.G1085S | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEA8 | c.515T>A p.V172E | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- MAGED1 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- MAOA | c.211G>T p.G71* | Nonsense Mutation (SNP) | VAF 38/370 reads (10%) | called by muse, mutect2, varscan2
- MAOA | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 38/368 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAP1A | c.4524T>A p.H1508Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); called by muse, mutect2
- MAP3K15 | c.382A>G p.S128G | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MAP7D2 | c.1566G>A p.M522I | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- MAP7D2 | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 82/327 reads (25%) | called by muse, mutect2, varscan2
- MAPKAPK3 | c.398G>T p.R133L | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MAPRE3 | c.388_399del p.R130_Q133del | In Frame Del (DEL) | VAF 25/86 reads (29%) | called by mutect2, pindel, varscan2
- MROH2B | c.4586-1G>C p.X1529_splice | Splice Site (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- MUC16 | c.31351G>T p.G10451C | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.753); called by muse, mutect2
- MUC16 | c.3068C>A p.T1023K | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- MUC2 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH8 | c.685del p.L229Yfs*11 | Frame Shift Del (DEL) | VAF 54/191 reads (28%) | called by mutect2, pindel, varscan2
- NALCN | c.2238G>T p.Q746H | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.006); called by muse, mutect2
- NAMPT | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NEDD8 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- NEK5 | c.396G>T p.Q132H | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NFKBIZ | c.469_470dup p.N157Kfs*33 | Frame Shift Ins (INS) | VAF 54/138 reads (39%) | called by mutect2, pindel, varscan2
- NGDN | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 16/75 reads (21%) | called by muse, mutect2, varscan2
- NLRP4 | c.1683G>T p.Q561H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- NMS | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- NOS1 | c.4100T>C p.I1367T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- NPHP1 | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 40/390 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2
- NPTX1 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- NTNG1 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR10G7 | c.563G>T p.C188F | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2L3 | c.857C>A p.P286H | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- OR4C6 | c.694C>A p.H232N | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PARP14 | c.1298T>A p.V433E | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2
- PARP14 | c.1530G>C p.L510F | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.028); called by muse, mutect2
- PARP4 | c.4274C>T p.S1425F | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDHX | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.437); called by muse, mutect2
- PER3 | c.1560G>T p.E520D | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PKP1 | c.2104G>T p.E702* | Nonsense Mutation (SNP) | VAF 9/129 reads (7%) | called by muse, mutect2
- PLA2G2E | c.9dup p.P4Sfs*56 | Frame Shift Ins (INS) | VAF 3/19 reads (16%) | called by pindel, varscan2
- PLXNC1 | c.1712T>A p.V571D | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- POLI | c.677C>G p.S226C | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- PPARG | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 10/276 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); called by muse, mutect2
- PPP1CA | c.242T>A p.F81Y | Missense Mutation (SNP) | VAF 75/175 reads (43%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PRAMEF6 | c.1237T>G p.Y413D | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRKDC | c.2684C>T p.A895V | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- PRPF38A | c.887C>G p.S296C | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.52); called by muse, mutect2
- PSMG4 | c.371_*2del | Frame Shift Del (DEL) | VAF 19/98 reads (19%) | called by mutect2, pindel, varscan2
- PTPN11 | c.714G>T p.E238D | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAB3GAP2 | c.2102C>T p.S701F | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.328); called by muse, mutect2
- RAD51AP2 | c.3057G>T p.M1019I | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- RFC1 | c.1259C>G p.S420C | Missense Mutation (SNP) | VAF 18/227 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.816); called by muse, mutect2
- RGS9 | c.582+1G>T p.X194_splice | Splice Site (SNP) | VAF 33/139 reads (24%) | called by muse, mutect2, varscan2
- RLIM | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); called by muse, mutect2
- RNF151 | c.169T>A p.C57S | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RTL3 | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- SAMD15 | c.661C>G p.L221V | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SCAF11 | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 16/220 reads (7%) | called by muse, mutect2
- SDK1 | c.2944G>A p.E982K | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- SENP7 | c.1654C>T p.Q552* | Nonsense Mutation (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- SIAE | c.1364C>G p.S455C | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- SLC11A2 | c.485T>C p.L162P (on ENST00000394904 / NM_001379455.1; = p.L133P on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC25A21 | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 97/273 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC4A1AP | c.1254T>G p.I418M | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- SLC6A3 | c.1505G>T p.G502V | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.191); called by muse, mutect2
- SLC9A2 | c.1792A>T p.T598S | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.026); called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1940T>C p.L647P (on ENST00000540229 / NM_001371097.1; = p.L586P on NM_001009562.4) | Missense Mutation (SNP) | VAF 37/218 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SMCHD1 | c.4892A>G p.D1631G | Missense Mutation (SNP) | VAF 5/111 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SPATA31A1 | c.1532C>A p.S511Y | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- SPEF2 | c.2866C>G p.L956V | Missense Mutation (SNP) | VAF 9/268 reads (3%) | SIFT tolerated (0.5); PolyPhen benign (0.009); called by muse, mutect2
- SPEN | c.5062G>A p.E1688K | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SRRM4 | c.179C>A p.S60* | Nonsense Mutation (SNP) | VAF 20/61 reads (33%) | called by muse, mutect2, varscan2
- STARD9 | c.2306C>G p.S769* | Nonsense Mutation (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
- STARD9 | c.3032A>T p.Y1011F | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- STON1 | c.1426G>C p.E476Q | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.698); called by muse, mutect2
- STYX | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- TDRD3 | c.502A>G p.N168D | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.063); called by muse, mutect2
- TEK | c.1567G>A p.G523R | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TM4SF18 | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMEM159 | c.169G>T p.V57L | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- TOP1MT | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 45/301 reads (15%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TPO | c.1546G>T p.G516W | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- TRDC | c.117G>C p.K39N | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.027); called by muse, mutect2
- TRPM6 | c.1750C>A p.H584N | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TSHZ1 | c.634T>G p.S212A (on ENST00000580243 / NM_001308210.2; = p.S167A on NM_005786.6) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TTC21A | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- TTN | c.64337G>T p.W21446L (on ENST00000591111; = p.W14022L on NM_003319.4) | Missense Mutation (SNP) | VAF 37/141 reads (26%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TXNRD3 | c.1063G>T p.G355C | Missense Mutation (SNP) | VAF 30/256 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBR4 | c.7291G>C p.G2431R | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- UBR4 | c.6319G>T p.A2107S | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); called by muse, mutect2
- UNC79 | c.1903G>T p.E635* (on ENST00000393151 / NM_001346218.2; = p.E458* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 89/135 reads (66%) | called by muse, mutect2, varscan2
- UNC80 | c.3737T>A p.V1246E | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- VSIG4 | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2
- WDR87 | c.8003C>A p.P2668H | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- WDR87 | c.8002C>A p.P2668T | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- WWC1 | c.2162C>T p.S721L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- YLPM1 | c.1458G>T p.Q486H | Missense Mutation (SNP) | VAF 66/116 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ZBTB37 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.14); called by muse, mutect2
- ZFC3H1 | c.3675G>C p.L1225F | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF184 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 75/276 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF479 | c.1362C>G p.D454E | Missense Mutation (SNP) | VAF 94/280 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- ZNF556 | c.915C>A p.H305Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF677 | c.1755G>T p.*585Yext*17 | Nonstop Mutation (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- ZNF721 | c.973G>A p.E325K (on ENST00000338977; = p.E337K on NM_133474.4) | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); called by muse, mutect2
- ZNF726 | c.1246A>C p.K416Q | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF91 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.045); called by muse, mutect2
- ABCC11 | c.3249C>A p.I1083= | Silent (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2
- AHNAK2 | c.12735G>A p.L4245= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV60909766; called by mutect2, varscan2
- AKT3 | c.714G>A p.S238= | Silent (SNP) | VAF 7/133 reads (5%) | catalogued as rs777277275; called by muse, mutect2
- AL592490.1 | c.1188C>T p.L396= | Silent (SNP) | VAF 41/105 reads (39%) | called by muse, mutect2, varscan2
- AQR | c.426A>G p.E142= | Silent (SNP) | VAF 9/161 reads (6%) | called by muse, mutect2
- ARHGAP22 | c.552G>T p.R184= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV99985772; called by muse, mutect2, varscan2
- BCHE | c.123C>G p.V41= | Silent (SNP) | VAF 37/208 reads (18%) | called by muse, mutect2, varscan2
- BCLAF3 | c.1821A>C p.I607= | Silent (SNP) | VAF 31/104 reads (30%) | called by muse, mutect2, varscan2
- CACNA1H | c.4362G>A p.G1454= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs1360673544; called by muse, varscan2
- CCDC138 | c.9G>T p.P3= | Silent (SNP) | VAF 4/33 reads (12%) | called by mutect2, varscan2
- CDKL5 | c.3054C>A p.L1018= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV101183759; called by muse, mutect2, varscan2
- CENPN | c.759A>G p.Q253= | Silent (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- CFTR | c.3498C>T p.F1166= | Silent (SNP) | VAF 26/244 reads (11%) | called by muse, mutect2, varscan2
- CNTD1 | c.648C>T p.V216= | Silent (SNP) | VAF 12/194 reads (6%) | catalogued as COSV59311744; called by muse, mutect2
- CNTN5 | c.2421C>T p.F807= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as rs751788662, COSV54285581; called by muse, mutect2, varscan2
- COL4A6 | c.2733A>G p.P911= | Silent (SNP) | VAF 11/133 reads (8%) | called by muse, mutect2
- CTNND2 | c.2727G>A p.V909= | Silent (SNP) | VAF 22/80 reads (28%) | called by muse, mutect2, varscan2
- DLG5 | c.957C>T p.A319= | Silent (SNP) | VAF 41/215 reads (19%) | called by muse, mutect2, varscan2
- DMBX1 | c.123G>T p.V41= | Silent (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
- ERVMER34-1 | c.1317T>G p.T439= | Silent (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- ETNPPL | c.867G>T p.V289= | Silent (SNP) | VAF 92/175 reads (53%) | called by muse, mutect2, varscan2
- F8 | c.909G>C p.A303= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV100811328; called by muse, mutect2
- FANCB | c.1923T>A p.P641= | Silent (SNP) | VAF 23/73 reads (32%) | called by muse, mutect2, varscan2
- FYB1 | c.876G>A p.K292= | Silent (SNP) | VAF 29/184 reads (16%) | catalogued as rs1256989476; called by muse, mutect2, varscan2
- GALNT15 | c.1857G>T p.P619= | Silent (SNP) | VAF 98/192 reads (51%) | catalogued as COSV100328044; called by muse, mutect2, varscan2
- HHAT | c.1311G>A p.S437= | Silent (SNP) | VAF 18/133 reads (14%) | catalogued as rs761262503, COSV54792842, COSV99801990; called by muse, mutect2, varscan2
- HOXA6 | c.192C>G p.V64= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as COSV56072410; called by muse, varscan2
- IFI27L2 | c.63G>A p.V21= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs757363423; called by mutect2, varscan2
- IL1B | c.378C>T p.L126= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as rs867828564, COSV54523596; called by muse, mutect2
- ITPR2 | c.5925C>G p.L1975= | Silent (SNP) | VAF 15/526 reads (3%) | called by muse, mutect2
- JAKMIP1 | c.216C>T p.L72= | Silent (SNP) | VAF 8/12 reads (67%) | called by muse, mutect2, varscan2
- JMJD1C | c.1641T>C p.S547= | Silent (SNP) | VAF 33/119 reads (28%) | called by muse, varscan2
- KIAA0100 | c.5463G>T p.V1821= | Silent (SNP) | VAF 48/114 reads (42%) | catalogued as COSV66492940; called by muse, mutect2, varscan2
- KIF5A | c.1077G>T p.T359= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV54058468, COSV99673334; called by muse, mutect2, varscan2
- KLF1 | c.48C>A p.A16= | Silent (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- LAMA2 | c.4419G>C p.L1473= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as COSV70347756; called by muse, mutect2, varscan2
- LIMK2 | c.774G>A p.Q258= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- LOXHD1 | c.3591C>T p.I1197= | Silent (SNP) | VAF 50/109 reads (46%) | called by muse, mutect2, varscan2
- LRPPRC | c.3540C>T p.I1180= | Silent (SNP) | VAF 25/380 reads (7%) | called by muse, mutect2
- MTUS2 | c.2826G>A p.Q942= | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as rs778916122; called by muse, mutect2, varscan2
- MYH6 | c.2040G>T p.R680= | Silent (SNP) | VAF 79/158 reads (50%) | called by muse, mutect2, varscan2
- NF1 | c.435C>T p.L145= | Silent (SNP) | VAF 7/137 reads (5%) | catalogued as rs876659818, COSV62207008; ClinVar: likely benign; called by muse, mutect2
- NPIPA2 | c.1041C>G p.L347= (on ENST00000529166; = p.L328= on NM_001277324.1) | Silent (SNP) | VAF 32/367 reads (9%) | catalogued as rs1192991486; called by muse, mutect2
- NTRK2 | c.318G>T p.V106= | Silent (SNP) | VAF 89/249 reads (36%) | called by muse, mutect2, varscan2
- NUDCD3 | c.1068G>T p.P356= | Silent (SNP) | VAF 15/38 reads (39%) | called by mutect2, varscan2
- OR2B2 | c.726C>T p.G242= | Silent (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- OR51B4 | c.291C>T p.T97= | Silent (SNP) | VAF 25/113 reads (22%) | catalogued as rs773674474; called by muse, varscan2
- OR7C2 | c.225C>A p.S75= | Silent (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- PARD3B | c.2250G>T p.L750= (on ENST00000406610 / NM_001302769.2; = p.L688= on NM_152526.6) | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as rs770310583; called by muse, mutect2, varscan2
- PCDHB6 | c.288C>A p.G96= | Silent (SNP) | VAF 40/67 reads (60%) | called by muse, mutect2, varscan2
- PDE8A | c.1374G>A p.G458= | Silent (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- PER3 | c.600G>T p.R200= | Silent (SNP) | VAF 33/140 reads (24%) | called by muse, mutect2, varscan2
- PER3 | c.1641G>A p.L547= | Silent (SNP) | VAF 7/84 reads (8%) | called by muse, mutect2
- PKHD1L1 | c.2988G>A p.Q996= | Silent (SNP) | VAF 20/236 reads (8%) | called by muse, mutect2
- PLPP4 | c.519G>T p.R173= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV64829032; called by muse, varscan2
- PPM1J | c.615A>G p.P205= | Silent (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- PRAMEF17 | c.723C>T p.F241= | Silent (SNP) | VAF 22/335 reads (7%) | called by muse, mutect2
- PRDX1 | c.324G>A p.P108= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as rs765244504; called by muse, mutect2, varscan2
- PRRX2 | c.585G>A p.L195= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs758622935; called by muse, mutect2
- PSG2 | c.102C>T p.A34= | Silent (SNP) | VAF 7/46 reads (15%) | called by muse, varscan2
- PYHIN1 | c.651G>A p.A217= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as rs761920064, COSV63722890; called by muse, mutect2
- SATB1 | c.1767A>T p.A589= | Silent (SNP) | VAF 33/52 reads (63%) | called by muse, mutect2, varscan2
- SLC16A2 | c.546C>T p.F182= | Silent (SNP) | VAF 12/244 reads (5%) | catalogued as COSV99330719; called by muse, mutect2
- SLC35B1 | c.777C>T p.F259= (on ENST00000649906; = p.F222= on NM_005827.4) | Silent (SNP) | VAF 12/214 reads (6%) | catalogued as COSV53602584; called by muse, mutect2
- SLCO5A1 | c.1497T>A p.G499= | Silent (SNP) | VAF 26/392 reads (7%) | catalogued as rs765558601; called by muse, mutect2
- SLX4 | c.1782C>T p.G594= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs1356071644; called by muse, varscan2
- SREBF2 | c.492C>T p.I164= | Silent (SNP) | VAF 29/152 reads (19%) | called by muse, mutect2, varscan2
- TAGLN3 | c.87G>A p.K29= | Silent (SNP) | VAF 38/69 reads (55%) | catalogued as rs746289605; called by muse, mutect2, varscan2
- TMEM117 | c.1359C>G p.T453= | Silent (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- TPM3 | c.402G>T p.R134= | Silent (SNP) | VAF 27/333 reads (8%) | catalogued as COSV55140155; called by muse, mutect2
- USP6NL | c.591C>G p.L197= | Silent (SNP) | VAF 12/110 reads (11%) | called by muse, mutect2
- VSIG2 | c.612C>T p.L204= | Silent (SNP) | VAF 16/140 reads (11%) | called by muse, mutect2, varscan2
- WDFY4 | c.4773C>G p.L1591= | Silent (SNP) | VAF 23/216 reads (11%) | called by muse, mutect2, varscan2
- WDR7 | c.3105G>C p.L1035= | Silent (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- WIPF2 | c.711G>A p.V237= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV60272728; called by muse, mutect2, varscan2
- XPO1 | c.1650A>G p.Q550= | Silent (SNP) | VAF 20/131 reads (15%) | called by muse, mutect2, varscan2
- ZNF257 | c.186C>T p.P62= | Silent (SNP) | VAF 22/222 reads (10%) | called by muse, mutect2
- ZNF675 | c.681C>G p.L227= | Silent (SNP) | VAF 33/134 reads (25%) | catalogued as rs531803624; called by muse, mutect2, varscan2
- ZNF713 | c.960G>C p.L320= (on ENST00000633730 / NM_001366796.2; = p.L333= on NM_182633.3) | Silent (SNP) | VAF 11/130 reads (8%) | called by muse, mutect2
- A2ML1 | c.1477-180G>C | Intron (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2
- ABCB8 | c.147-594del | Intron (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- AC009237.3 | n.724G>A | RNA (SNP) | VAF 9/156 reads (6%) | called by muse, mutect2
- AC024940.1 | n.4875G>C | RNA (SNP) | VAF 9/116 reads (8%) | called by muse, mutect2
- AGK | c.141+142G>T | Intron (SNP) | VAF 23/149 reads (15%) | catalogued as COSV100814672, COSV62594798; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503270 C>G | 5'Flank (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500419 C>T | 5'Flank (SNP) | VAF 23/340 reads (7%) | called by muse, mutect2
- ARHGEF4 | c.-166C>A | 5'UTR (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- ATAD2B | c.784+1133G>C | Intron (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- BABAM2 | c.681-3991C>T | Intron (SNP) | VAF 28/134 reads (21%) | called by muse, mutect2, varscan2
- C1QTNF1 | c.-232+1394T>C | Intron (SNP) | VAF 34/137 reads (25%) | catalogued as rs1394577467; called by muse, varscan2
- C7orf25 | c.-21-140A>T | Intron (SNP) | VAF 13/222 reads (6%) | called by muse, mutect2
- CARTPT | c.160-36G>T | Intron (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- CD8A | c.*877A>G | 3'UTR (SNP) | VAF 12/161 reads (7%) | called by muse, mutect2
- CD96 | c.*7G>T | 3'UTR (SNP) | VAF 20/157 reads (13%) | called by muse, mutect2, varscan2
- CHIT1 | c.*536A>T | 3'UTR (SNP) | VAF 29/118 reads (25%) | called by muse, mutect2, varscan2
- CHRNA4 | c.383+10C>G | Intron (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2
- CLN3 | c.834+19G>A | Intron (SNP) | VAF 12/70 reads (17%) | called by muse, mutect2, varscan2
- CRYZL1 | c.-7+494G>T | Intron (SNP) | VAF 36/98 reads (37%) | called by muse, mutect2, varscan2
- CXorf56 | c.243-983G>A | Intron (SNP) | VAF 7/142 reads (5%) | called by muse, mutect2
- DAAM2 | c.*2568G>A | 3'UTR (SNP) | VAF 20/262 reads (8%) | called by muse, mutect2
- DCAF17 | c.*3540A>T | 3'UTR (SNP) | VAF 65/189 reads (34%) | called by muse, mutect2, varscan2
- DRD2 | c.810+57C>A | Intron (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2, varscan2
- DYSF | c.3844-9T>C | Intron (SNP) | VAF 10/201 reads (5%) | called by muse, mutect2
- GLIPR1L1 | c.611-2990C>A | Intron (SNP) | VAF 38/422 reads (9%) | called by muse, mutect2
- JAKMIP2 | c.2413-2733G>A | Intron (SNP) | VAF 66/130 reads (51%) | catalogued as rs1285350092; called by muse, mutect2, varscan2
- KCNH7 | chr2:162371368 C>T | 3'Flank (SNP) | VAF 25/116 reads (22%) | called by muse, mutect2, varscan2
- LIG1 | c.2584-13C>G | Intron (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- LPIN1 | c.722+2442C>T | Intron (SNP) | VAF 23/140 reads (16%) | catalogued as rs1048061286; called by muse, mutect2, varscan2
- MEG3 | n.1244G>T | RNA (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- MIR519B | n.69G>C | RNA (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- NEUROG3 | c.*26G>A | 3'UTR (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- PAX1 | c.*35G>T | 3'UTR (SNP) | VAF 59/103 reads (57%) | called by muse, mutect2, varscan2
- PLEKHA8P1 | n.924G>A | RNA (SNP) | VAF 26/148 reads (18%) | called by muse, mutect2, varscan2
- PLEKHB1 | c.248-340C>G | Intron (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- PRR14 | c.24-50G>A | Intron (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- RELL1 | c.89-15852T>G | Intron (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- RESP18 | c.466-132C>G | Intron (SNP) | VAF 26/167 reads (16%) | catalogued as rs1299319476; called by muse, mutect2, varscan2
- RMDN2 | c.452+21939G>C | Intron (SNP) | VAF 12/188 reads (6%) | called by muse, mutect2
- SART1 | c.981+27G>C | Intron (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- SP110 | chr2:230221748 C>T | 5'Flank (SNP) | VAF 20/111 reads (18%) | called by muse, mutect2, varscan2
- SYT14 | chr1:210163027 G>C | 3'Flank (SNP) | VAF 13/118 reads (11%) | called by muse, mutect2, varscan2
- TEDC1 | chr14:105491087 C>T | 5'Flank (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- TMEM159 | c.97-3527A>T | Intron (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2
- TMEM164 | c.391-11998C>A | Intron (SNP) | VAF 13/111 reads (12%) | called by muse, mutect2, varscan2
- TMEM225B | c.-12G>A | 5'UTR (SNP) | VAF 17/86 reads (20%) | called by muse, mutect2, varscan2
- TRIM39 | c.1010-253C>T | Intron (SNP) | VAF 15/81 reads (19%) | catalogued as rs1043642864; called by muse, mutect2, varscan2
- UQCRB | c.*150G>C | 3'UTR (SNP) | VAF 27/137 reads (20%) | called by muse, mutect2, varscan2
- USP46 | c.36+846G>A | Intron (SNP) | VAF 6/61 reads (10%) | called by muse, mutect2, varscan2
- VAPB | c.*5629G>T | 3'UTR (SNP) | VAF 38/78 reads (49%) | called by muse, mutect2, varscan2
- YME1L1 | c.*102G>T | 3'UTR (SNP) | VAF 25/130 reads (19%) | called by muse, mutect2, varscan2
- ZBBX | c.2138-9561C>G | Intron (SNP) | VAF 9/199 reads (5%) | called by muse, mutect2
- ZNF304 | c.-18A>G | 5'UTR (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
